TCGA case TCGA-E1-5319 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/84569c1a-6baa-4380-ae3c-707df1be4618

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 48 years; Vital status: Dead; Days to death: 2,907 days (8.0 years).

Diagnoses (2)
1. Oligodendroglioma, NOS (the primary disease): ICD-O-3 morphology code: 9450/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 48.2 years (17,612 days); Year of diagnosis: 1998; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Visual Changes; Sites of involvement: Brain, Frontal lobe.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 952 days (2.6 years); Days to treatment end: 1,385 days (3.8 years); Number of cycles: 13; Treatment dose: 26,650 mg; Prescribed dose: 200; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Celecoxib; Treatment intent type: Adjuvant; Days to treatment start: 1,385 days (3.8 years); Days to treatment end: 1,511 days (4.1 years); Number of cycles: 4; Treatment dose: 95,200 mg; Prescribed dose: 800; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,826 days (5.0 years); Days to treatment end: 1,933 days (5.3 years); Number of cycles: 3; Treatment dose: 94,920 mg; Prescribed dose: 560; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,933 days (5.3 years); Days to treatment end: 1,993 days (5.5 years); Number of cycles: 2; Treatment dose: 50,400 mg; Prescribed dose: 450; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 2,029 days (5.6 years); Days to treatment end: 2,121 days (5.8 years); Number of cycles: 2; Treatment dose: 4,000 mg; Prescribed dose: 200; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 2,243 days (6.1 years); Days to treatment end: 2,304 days (6.3 years); Treatment dose: 6,000 cGy; Course number: 5; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Initial disease status: Progressive Disease; Days to treatment start: 2,322 days (6.4 years); Days to treatment end: 2,364 days (6.5 years); Number of cycles: 1; Treatment dose: 240 mg; Prescribed dose: 110; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Initial disease status: Progressive Disease; Days to treatment start: 2,364 days (6.5 years); Days to treatment end: 2,433 days (6.7 years); Number of cycles: 1; Treatment dose: 180 mg; Prescribed dose: 82.5; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Progressive Disease; Days to treatment start: 2,433 days (6.7 years); Days to treatment end: 2,587 days (7.1 years); Number of cycles: 3; Treatment dose: 6,300 mg; Prescribed dose: 50; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 2,587 days (7.1 years); Days to treatment end: 2,818 days (7.7 years); Number of cycles: 6; Treatment dose: 6,300 mg; Prescribed dose: 25; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Treatment given: Treatment type: Steroid Therapy; Timepoint category: Preoperative.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.
2. Recurrence of diagnosis 1 (Oligodendroglioma, NOS). Age at diagnosis: 50.7 years (18,535 days); Days to diagnosis: 923 days (2.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 923 days (2.5 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Distant Site.

Follow-up (4 entries)
- Day 923 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 923 days (2.5 years).
- Day 936 (prior to adjuvant therapy): Karnofsky performance status: 100.
- Day 952 (prior to adjuvant therapy): Karnofsky performance status: 100.
- Days to follow up: 2,907 days (8.0 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Vision Changes.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-E1-5319-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.5.
  Slide TCGA-E1-5319-01A-01-BS1: Section location: Bottom; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-E1-5319-01A-01-TS1: Section location: Top; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-E1-5319-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligodendroglioma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy; Tumor site: Supratentorial, Frontal Lobe; Supratentorial localization: Not listed in Medical Record; History seizures: No; History headaches: No; Symp changes mental status: No; Symp changes visual: Yes; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: 0 - 30 Days; History asthma: No; History eczema: No; Histor hay fever: No; History neoadjuvant steroid treatment: Yes; History neoadjuvant medication: Yes.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Temodar; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 2; Pharmaceutical therapy drug name: Celebrex.
- Drug treatment 3: Regimen number: 4; Therapy regimen: Progression.
- Drug treatment 4: Regimen number: 3; Therapy regimen: Progression.
- Drug treatment 5: Regimen number: 6; Pharmaceutical therapy drug name: Ccnu; Therapy regimen: Progression.
- Drug treatment 6: Regimen number: 5; Pharmaceutical therapy drug name: Temodar; Therapy regimen: Progression.
- Drug treatment 7: Regimen number: 7; Pharmaceutical therapy drug name: Ccnu; Therapy regimen: Progression.
- Drug treatment 8: Regimen number: 8; Pharmaceutical therapy drug name: VP-16; Therapy regimen: Progression.
- Drug treatment 9: Regimen number: 9; Pharmaceutical therapy drug name: VP-16.
- Follow-up form: Treatment outcome first course: Stable Disease; New tumor event surgery: Yes; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; New tumor event radiation treatment: Yes; Performance status timing: Pre-Adjuvant Therapy; Treatment outcome at TCGA followup: Stable Disease; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,907 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,907 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 923 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-E1-5319-01A-01D-1892-01): tumor purity 0.7, ploidy 1.94, whole-genome doublings 0.
